TCGA case TCGA-28-2510 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Cedars Sinai.
https://portal.gdc.cancer.gov/cases/6ccd57e5-9215-46fa-b3be-e408a0f424dc

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-28-2510-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2.1; Intermediate dimension: 0.9; Shortest dimension: 0.4.
  Slide TCGA-28-2510-01A-01-TS1: Section location: Top; Percent tumor cells: 30; Percent tumor nuclei: 60; Percent normal cells: 65; Percent necrosis: 5; Percent stromal cells: 0.
  Slide TCGA-28-2510-01A-01-BS1: Section location: Bottom; Percent tumor cells: 40; Percent tumor nuclei: 10; Percent normal cells: 60; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-28-2510-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-28-2510-01A-01D-1694-01): tumor purity 0.3, ploidy 2.05, whole-genome doublings 0.
